Somatic mutation profile of tumor specimen C3L-09775-01 (aliquot CPT0533050014) from CPTAC case C3L-09775, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.1 years (23,768 days).
Specimen C3L-09775-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db6fba98-bc0c-47a1-a418-5bd61038655b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09775-31 (Blood Derived Normal), aliquot CPT0533140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2eef9be8-0090-4f8d-9f22-c66ce23d74a4

The open-access MAF lists 301 somatic variants for this specimen: 223 protein-altering or splice-affecting, 73 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 73, Nonsense Mutation 12, Intron 4, Frame Shift Del 2, Frame Shift Ins 1, 5'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 40/247 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, mutect2, varscan2
- CDKN2A | c.35C>A p.S12* | Nonsense Mutation (SNP) | VAF 101/377 reads (27%) | hotspot (GDC flag); catalogued as rs141798398, CM072935, COSV58687783, COSV58689693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 30/255 reads (12%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 99/283 reads (35%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC139530.2 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61367013; called by muse, mutect2
- ADAMTS6 | c.2786A>T p.K929M | Missense Mutation (SNP) | VAF 77/378 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs770006465; called by muse, mutect2, varscan2
- ADARB2 | c.1241A>G p.K414R | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101187334; called by muse, mutect2, varscan2
- ADPRHL1 | c.379+1G>A p.X127_splice | Splice Site (SNP) | VAF 40/286 reads (14%) | catalogued as rs1322207769; called by muse, mutect2, varscan2
- AP3B2 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464177208; called by muse, mutect2, varscan2
- APC2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 81/499 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52018578; called by muse, mutect2, varscan2
- BRF1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1171973014; called by muse, mutect2, varscan2
- CCDC168 | c.18437G>A p.S6146N | Missense Mutation (SNP) | VAF 142/359 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as rs541635632; called by muse, mutect2, varscan2
- CD5L | c.636A>C p.E212D | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100941110; called by muse, mutect2, varscan2
- CDH5 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 133/375 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV58518821; called by muse, mutect2, varscan2
- CDH9 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 63/322 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs768684659, COSV50281922; called by muse, mutect2, varscan2
- CEP78 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 11/271 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV52851032; called by muse, mutect2
- CNTNAP5 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 19/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101444401, COSV70498945; called by muse, mutect2
- DDX59 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 44/366 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58752910; called by muse, mutect2, varscan2
- DLG2 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV65832294, COSV65853967; called by muse, mutect2, varscan2
- EFCAB1 | c.464A>C p.K155T | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100030979; called by muse, mutect2
- EFCAB5 | c.1478T>G p.L493R | Missense Mutation (SNP) | VAF 16/508 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV57933771; called by muse, mutect2
- ENPEP | c.271T>A p.F91I | Missense Mutation (SNP) | VAF 162/434 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99488267; called by muse, mutect2, varscan2
- FBN1 | c.6545A>G p.K2182R | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV57327570; called by muse, mutect2, varscan2
- FUT9 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.147); catalogued as rs753422213; called by muse, mutect2, varscan2
- GLP2R | c.826T>G p.L276V | Missense Mutation (SNP) | VAF 55/325 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV99301512, COSV99301616; called by muse, mutect2, varscan2
- GYS2 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 105/291 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.914); catalogued as COSV53927070; called by muse, mutect2, varscan2
- H2AC17 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 53/381 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58152506, COSV58153617; called by muse, mutect2, varscan2
- HHLA1 | c.10T>G p.F4V | Missense Mutation (SNP) | VAF 33/511 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs1461249333; called by muse, mutect2
- HK3 | c.976T>A p.L326M | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.193); catalogued as rs1561682092, COSV99459770; called by muse, mutect2, varscan2
- HS3ST4 | c.1309T>G p.L437V | Missense Mutation (SNP) | VAF 158/350 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58815218, COSV58819212; called by muse, mutect2, varscan2
- HSP90AA1 | c.52C>T p.R18W | Missense Mutation (SNP) | VAF 25/513 reads (5%) | PolyPhen benign (0); catalogued as COSV100084897; called by muse, mutect2
- IGFBP2 | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 45/631 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as rs780818147; called by muse, mutect2
- IL1RAPL2 | c.453A>C p.K151N | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV61159617, COSV61190466; called by muse, mutect2, varscan2
- IP6K2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs575264529, COSV60793798; called by muse, mutect2, varscan2
- KCNB2 | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 260/515 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV73052771; called by muse, mutect2, varscan2
- KCNH1 | c.679T>G p.L227V | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55070444; called by muse, mutect2
- KDM5B | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 107/349 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs1430157030, COSV52505925; called by muse, mutect2, varscan2
- KLK5 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 32/642 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV60450647; called by muse, mutect2
- KMT2B | c.4053G>C p.E1351D | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.226); catalogued as rs773034213; called by muse, mutect2
- MICALL2 | c.2525A>G p.E842G | Missense Mutation (SNP) | VAF 100/407 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.157); catalogued as rs1268473964; called by muse, mutect2, varscan2
- MSN | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV64305779; called by muse, mutect2, varscan2
- MTUS2 | c.2192A>G p.K731R | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2, varscan2
- MYO16 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51787442, COSV51819118; called by muse, mutect2, varscan2
- NAPRT | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 224/802 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1340197075, COSV52784890; called by muse, mutect2, varscan2
- NOTCH3 | c.5944G>A p.E1982K | Missense Mutation (SNP) | VAF 28/445 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54655028; called by muse, mutect2
- NPAP1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 22/565 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.322); catalogued as rs1200121129, COSV100274495; called by muse, mutect2
- NRG1 | c.269A>G p.K90R (on ENST00000523534; = p.K237R on NM_013962.2) | Missense Mutation (SNP) | VAF 110/343 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs1199092704; called by muse, mutect2, varscan2
- NRG1 | c.848G>A p.R283Q (on ENST00000405005 / NM_013964.5; = p.R288Q on NM_013956.5) | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs145033301, COSV99829962; called by muse, mutect2, varscan2
- OR13C9 | c.557A>G p.K186R | Missense Mutation (SNP) | VAF 67/382 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs755694979; called by muse, mutect2, varscan2
- OR1A2 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67936076, COSV67936583; called by muse, mutect2
- OR4C16 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58941903; called by muse, mutect2
- OR5L2 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65723759; called by muse, mutect2, varscan2
- OR5M3 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100392520, COSV56565606; called by muse, mutect2, varscan2
- PADI1 | c.151T>C p.F51L | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs1231597708; called by muse, mutect2, varscan2
- PCLO | c.7390A>G p.T2464A | Missense Mutation (SNP) | VAF 98/518 reads (19%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV100438342; called by muse, varscan2
- PDCD2L | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 14/514 reads (3%) | catalogued as rs1568361403; called by muse, mutect2
- PGA3 | c.198del p.Q66Hfs*77 | Frame Shift Del (DEL) | VAF 40/329 reads (12%) | catalogued as COSV100337396; called by mutect2, varscan2
- PREX2 | c.4734G>T p.K1578N | Missense Mutation (SNP) | VAF 42/473 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55759704, COSV55790642; called by muse, mutect2
- PRRC2A | c.2932C>G p.P978A | Missense Mutation (SNP) | VAF 153/677 reads (23%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV65685494; called by muse, mutect2, varscan2
- PRUNE2 | c.6200C>T p.A2067V | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs374932024, COSV104428525; called by muse, mutect2, varscan2
- PSG8 | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs1328446571; called by muse, mutect2
- RIMS2 | c.2192T>G p.L731R (on ENST00000666250 / NM_001348490.2; = p.L539R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51710324; called by muse, mutect2, varscan2
- RNF17 | c.2218G>T p.G740* | Nonsense Mutation (SNP) | VAF 52/257 reads (20%) | catalogued as COSV55036160; called by muse, mutect2, varscan2
- RP1L1 | c.1130C>G p.S377* | Nonsense Mutation (SNP) | VAF 26/452 reads (6%) | catalogued as COSV66759184; called by muse, mutect2
- SH3GL2 | c.974A>G p.E325G | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV66047825; called by muse, mutect2, varscan2
- SLC4A3 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 32/517 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1559196296; called by muse, mutect2
- SLCO1B3 | c.1130T>G p.L377W | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV53937840, COSV99680986; called by muse, mutect2, varscan2
- SLIT2 | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56558833; called by muse, mutect2, varscan2
- SMURF1 | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 27/606 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63158694; called by muse, mutect2
- SPDYE3 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT tolerated (0.4); catalogued as rs1267451852; called by muse, mutect2
- SPDYE5 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 58/706 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs1355225344; called by muse, mutect2, varscan2
- SPEF2 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs749222780, COSV56798202; called by muse, mutect2, varscan2
- SRGAP3 | c.1448T>G p.L483R | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as rs924953999; called by mutect2, varscan2
- STAC3 | c.1055A>G p.K352R | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773171630; called by muse, mutect2
- STX5 | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 119/376 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.143); catalogued as COSV53677890; called by mutect2, varscan2
- SUGCT | c.1033A>G p.S345G | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1238995939; called by muse, mutect2, varscan2
- SYNE1 | c.18654A>C p.Q6218H (on ENST00000367255 / NM_182961.4; = p.Q6147H on NM_033071.3) | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV55005811; called by muse, mutect2
- TBCEL | c.1117A>C p.K373Q | Missense Mutation (SNP) | VAF 93/402 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.39); catalogued as COSV99412398; called by muse, mutect2, varscan2
- THRB | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM021153, COSV54983024; called by muse, mutect2, varscan2
- TMEM81 | c.422A>C p.N141T | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1402899952; called by muse, mutect2
- TRO | c.4105G>A p.G1369S | Missense Mutation (SNP) | VAF 163/348 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.3); catalogued as rs376279271, COSV99436672, COSV99437376; called by muse, mutect2, varscan2
- TRPC7 | c.2349C>G p.I783M | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV61457377; called by muse, mutect2
- TTN | c.101737G>A p.E33913K (on ENST00000591111; = p.E26489K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/332 reads (8%) | PolyPhen benign (0.031); catalogued as rs1165517840; called by muse, mutect2
- VWF | c.4105T>G p.F1369V | Missense Mutation (SNP) | VAF 154/450 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM910404; called by muse, mutect2, varscan2
- WDFY4 | c.4624T>G p.F1542V | Missense Mutation (SNP) | VAF 14/343 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); catalogued as COSV100300755; called by muse, mutect2
- ZC3H12B | c.1077A>C p.Q359H | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59047092; called by muse, mutect2, varscan2
- ZFHX4 | c.3906G>C p.E1302D | Missense Mutation (SNP) | VAF 14/470 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.275); catalogued as COSV99265658; called by muse, mutect2
- ZFHX4 | c.7373T>G p.L2458R | Missense Mutation (SNP) | VAF 28/844 reads (3%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.165); catalogued as COSV50589877, COSV51476909; called by muse, mutect2
- ZMAT1 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100858937; called by muse, mutect2
- ZNF132 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 132/498 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99571161; called by muse, mutect2, varscan2
- ZNF257 | c.1349A>C p.K450T | Missense Mutation (SNP) | VAF 148/339 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV71309813, COSV71313366; called by muse, mutect2, varscan2
- ZSCAN18 | c.5G>A p.R2Q | Missense Mutation (SNP) | VAF 12/416 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as rs1473916096; called by muse, mutect2
- ABCD1 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 11/303 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2
- ADGRB1 | c.607T>C p.S203P | Missense Mutation (SNP) | VAF 437/836 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- AGTPBP1 | c.1876G>A p.D626N (on ENST00000357081 / NM_001330701.2; = p.D586N on NM_015239.2) | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- AMPH | c.2066A>C p.N689T | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKFN1 | c.1690T>C p.W564R | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- APC2 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ARHGEF28 | c.3079T>G p.L1027V | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF9 | c.134G>A p.W45* | Nonsense Mutation (SNP) | VAF 29/276 reads (11%) | called by muse, mutect2, varscan2
- ATG9A | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- B4GALT6 | c.984A>C p.E328D | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- BAZ2B | c.5749C>T p.Q1917* | Nonsense Mutation (SNP) | VAF 24/368 reads (7%) | called by muse, mutect2
- BCL7B | c.75C>G p.I25M | Missense Mutation (SNP) | VAF 71/501 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- BRSK2 | c.510C>A p.S170R | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- C5orf51 | c.590T>G p.L197* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | called by muse, mutect2, varscan2
- CAPNS1 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 13/373 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by muse, mutect2
- CARM1 | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- CENPC | c.1127C>G p.S376C | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- CHRM2 | c.74T>G p.F25C | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2
- CLPP | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 17/406 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- COL5A3 | c.3499T>G p.S1167A | Missense Mutation (SNP) | VAF 160/341 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL6A5 | c.6927A>C p.E2309D (on ENST00000312481; = p.E2305D on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- COPS3 | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPQ | c.449T>G p.V150G | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- CRACR2A | c.890A>C p.D297A | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- CTNND2 | c.3422C>T p.S1141L | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.112); called by muse, mutect2
- DAGLB | c.1030T>G p.F344V | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DCAF8 | c.1412A>G p.Q471R | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- DMXL1 | c.4487C>T p.S1496F | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DOCK4 | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 27/654 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2
- DRP2 | c.2512G>T p.E838* | Nonsense Mutation (SNP) | VAF 171/325 reads (53%) | called by muse, mutect2, varscan2
- DSEL | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 96/422 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- DYNC2H1 | c.8388T>A p.N2796K | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- ERBB4 | c.2572A>G p.K858E | Missense Mutation (SNP) | VAF 185/394 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERBIN | c.3247A>C p.T1083P | Missense Mutation (SNP) | VAF 13/272 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.132); called by muse, mutect2
- ESPN | c.2675G>A p.G892D | Missense Mutation (SNP) | VAF 62/350 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAM118B | c.320T>A p.L107H | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- FAM71E2 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 18/463 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2
- FIGN | c.1232T>C p.L411S | Missense Mutation (SNP) | VAF 40/452 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, mutect2
- FNIP1 | c.1660T>G p.L554V | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FOLH1 | c.1691A>G p.K564R | Missense Mutation (SNP) | VAF 52/203 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FOXK1 | c.1850T>G p.L617R | Missense Mutation (SNP) | VAF 149/549 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FSIP2 | c.7913A>G p.N2638S | Missense Mutation (SNP) | VAF 27/327 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- GGTLC1 | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 191/593 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- GIMAP1 | c.237A>C p.E79D | Missense Mutation (SNP) | VAF 15/415 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2
- GOLGA6B | c.1046A>T p.Q349L | Missense Mutation (SNP) | VAF 103/544 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GOLGB1 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- GPR146 | c.841T>C p.S281P | Missense Mutation (SNP) | VAF 139/506 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GRM3 | c.1891T>C p.F631L | Missense Mutation (SNP) | VAF 91/492 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HJV | c.1198G>A p.D400N (on ENST00000336751 / NM_213653.4; = p.D287N on NM_145277.5) | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.76); called by muse, mutect2
- HTR3D | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRX5 | c.1327A>C p.N443H | Missense Mutation (SNP) | VAF 10/344 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2
- IVL | c.1175A>C p.Q392P | Missense Mutation (SNP) | VAF 78/602 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KCND1 | c.1763A>C p.N588T | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- KDM5A | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 19/391 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); called by muse, mutect2
- KLHL4 | c.1835T>G p.V612G | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KNTC1 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KRTAP21-3 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 41/119 reads (34%) | PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- LILRB5 | c.916T>G p.S306A | Missense Mutation (SNP) | VAF 22/733 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRP1B | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 144/329 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, varscan2
- LRRC6 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC7 | c.3805dup p.I1269Nfs*4 (on ENST00000651989 / NM_001370785.2; = p.I1236Nfs*4 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 44/274 reads (16%) | called by mutect2, pindel, varscan2
- MAP1B | c.3752T>G p.V1251G | Missense Mutation (SNP) | VAF 62/389 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAPK10 | c.499A>T p.I167F (on ENST00000359221 / NM_001351625.2; = p.I205F on NM_002753.5) | Missense Mutation (SNP) | VAF 98/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAST3 | c.3344C>A p.S1115Y | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MDGA2 | c.2317T>G p.L773V (on ENST00000399232 / NM_001113498.2; = p.L475V on NM_182830.4) | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEIKIN | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPV17L2 | c.553T>G p.L185V | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- MUC16 | c.22333A>C p.T7445P | Missense Mutation (SNP) | VAF 20/506 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); called by muse, mutect2
- MUC16 | c.10106T>A p.L3369H | Missense Mutation (SNP) | VAF 159/390 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MUC19 | c.137T>G p.V46G | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH4 | c.3593A>G p.K1198R | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- NME8 | c.1342T>C p.F448L | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOS3 | c.1664A>C p.E555A | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2
- NPAS1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 34/700 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2
- NRK | c.1933A>T p.R645* | Nonsense Mutation (SNP) | VAF 122/262 reads (47%) | called by muse, mutect2, varscan2
- OR2A5 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 93/312 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- OR2J2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 63/465 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR51E2 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- OR5H8 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR8J2 | c.829T>G p.F277V | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OSGIN2 | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 22/650 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- PDPN | c.286A>C p.S96R (on ENST00000621990; = p.S172R on NM_006474.4) | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PGA3 | c.202del p.L68Wfs*75 | Frame Shift Del (DEL) | VAF 38/422 reads (9%) | called by mutect2*, pindel, varscan2*
- PITPNM1 | c.2062T>C p.F688L | Missense Mutation (SNP) | VAF 93/455 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R3A | c.120A>C p.Q40H | Missense Mutation (SNP) | VAF 86/482 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- PRAMEF1 | c.1150T>G p.F384V | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); called by muse, mutect2
- PREX2 | c.4301A>C p.N1434T | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PRKCH | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 15/247 reads (6%) | called by muse, mutect2
- PTPRG | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PTPRH | c.1910C>A p.P637H | Missense Mutation (SNP) | VAF 31/678 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- RBFOX1 | c.1117G>C p.D373H | Missense Mutation (SNP) | VAF 27/372 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.436); called by muse, mutect2
- RC3H1 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.193); called by muse, mutect2
- RELN | c.1049T>G p.I350S | Missense Mutation (SNP) | VAF 92/461 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RYR3 | c.6571G>A p.E2191K | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCAF8 | c.3429A>C p.Q1143H | Missense Mutation (SNP) | VAF 84/332 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SCN5A | c.3366A>C p.E1122D (on ENST00000333535 / NM_198056.3; = p.E1121D on NM_000335.5) | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCRIB | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 23/732 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); called by muse, mutect2
- SEMA5A | c.1289A>C p.K430T | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SGCD | c.727C>A p.P243T (on ENST00000435422 / NM_001128209.2; = p.P244T on NM_000337.5) | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.684); called by muse, mutect2
- SGCG | c.308T>G p.L103R | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SLC13A3 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 16/535 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC16A9 | c.809A>C p.K270T | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); called by muse, mutect2
- SLF1 | c.1728T>A p.F576L | Missense Mutation (SNP) | VAF 57/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLITRK1 | c.39T>G p.C13W | Missense Mutation (SNP) | VAF 133/337 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SMIM12 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 11/352 reads (3%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.646); called by muse, mutect2
- SOX3 | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 177/381 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPNS3 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 141/417 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- SYNCRIP | c.1360T>G p.Y454D | Missense Mutation (SNP) | VAF 49/302 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SYNE1 | c.4481A>G p.E1494G (on ENST00000367255 / NM_182961.4; = p.E1501G on NM_033071.3) | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCEAL5 | c.403T>G p.L135V | Missense Mutation (SNP) | VAF 164/340 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- TCF20 | c.5764G>C p.E1922Q | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TECPR1 | c.1257A>C p.E419D | Missense Mutation (SNP) | VAF 38/730 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- TLL1 | c.1874T>G p.L625R | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF1 | c.541T>G p.F181V | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2
- TRPC7 | c.1654T>G p.F552V | Missense Mutation (SNP) | VAF 76/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRRAP | c.5980T>G p.F1994V (on ENST00000359863 / NM_001244580.1; = p.F1976V on NM_003496.3) | Missense Mutation (SNP) | VAF 136/562 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- TTN | c.87634A>T p.I29212L (on ENST00000591111; = p.I21788L on NM_003319.4) | Missense Mutation (SNP) | VAF 32/459 reads (7%) | PolyPhen probably damaging (0.978); called by muse, mutect2
- TUBGCP3 | c.2324T>G p.L775R | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- USH2A | c.7189G>A p.V2397M | Missense Mutation (SNP) | VAF 14/427 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.294); called by muse, mutect2
- VAV1 | c.1788G>C p.K596N | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2
- VIRMA | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- WASL | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 31/434 reads (7%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.607); called by muse, mutect2
- WDR49 | c.1685T>G p.L562R (on ENST00000308378 / NM_001366158.1; = p.L903R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2
- WDR81 | c.4207A>G p.S1403G (on ENST00000409644 / NM_001163809.2; = p.S352G on NM_152348.4) | Missense Mutation (SNP) | VAF 75/558 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ZBBX | c.2390C>A p.S797* | Nonsense Mutation (SNP) | VAF 37/154 reads (24%) | called by muse, mutect2, varscan2
- ZCCHC12 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 108/238 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- ZNF415 | c.145C>G p.R49G | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- ZNF462 | c.5153A>G p.K1718R | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); called by muse, varscan2
- ZNF585B | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 21/573 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF618 | c.1714G>A p.E572K (on ENST00000374126 / NM_001318042.2; = p.E479K on NM_133374.2) | Missense Mutation (SNP) | VAF 106/397 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF813 | c.1487A>G p.K496R | Missense Mutation (SNP) | VAF 160/556 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.166); called by muse, mutect2
- ACAN | c.6471A>G p.Q2157= | Silent (SNP) | VAF 71/355 reads (20%) | called by muse, mutect2, varscan2
- ADAM15 | c.2589C>G p.L863= (on ENST00000356955 / NM_207197.3; = p.L814= on NM_003815.5) | Silent (SNP) | VAF 30/420 reads (7%) | called by muse, mutect2
- AMN1 | c.360T>G p.A120= | Silent (SNP) | VAF 18/396 reads (5%) | called by muse, mutect2
- ANGPTL6 | c.36G>C p.L12= | Silent (SNP) | VAF 14/498 reads (3%) | called by muse, mutect2
- ARFGEF3 | c.4167C>G p.L1389= | Silent (SNP) | VAF 10/290 reads (3%) | called by muse, mutect2
- ARHGAP28 | c.1260T>C p.F420= (on ENST00000383472 / NM_001366230.1; = p.F261= on NM_001010000.3) | Silent (SNP) | VAF 93/236 reads (39%) | called by muse, mutect2, varscan2
- ASTN2 | c.1227T>C p.T409= (on ENST00000313400 / NM_001365069.1; = p.T358= on NM_014010.5) | Silent (SNP) | VAF 71/312 reads (23%) | called by muse, mutect2, varscan2
- ATXN7 | c.1233C>T p.L411= | Silent (SNP) | VAF 22/446 reads (5%) | called by muse, mutect2
- AVP | c.207G>C p.T69= | Silent (SNP) | VAF 214/640 reads (33%) | catalogued as rs747554567; called by muse, varscan2
- BCOR | c.5070C>T p.V1690= (on ENST00000378444 / NM_001123385.2; = p.V1656= on NM_017745.6) | Silent (SNP) | VAF 31/222 reads (14%) | called by muse, mutect2, varscan2
- CELF4 | c.939C>T p.T313= | Silent (SNP) | VAF 95/219 reads (43%) | catalogued as rs746025688; called by muse, mutect2, varscan2
- CNTN6 | c.654T>C p.T218= | Silent (SNP) | VAF 19/176 reads (11%) | catalogued as COSV63176587; called by muse, mutect2, varscan2
- DAAM2 | c.1719T>C p.P573= | Silent (SNP) | VAF 44/367 reads (12%) | catalogued as COSV99224365; called by mutect2, varscan2
- DDX60 | c.4092C>T p.L1364= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as rs369482931; called by muse, mutect2
- E4F1 | c.27G>A p.V9= | Silent (SNP) | VAF 20/466 reads (4%) | called by muse, mutect2
- FAM163B | c.264C>T p.R88= | Silent (SNP) | VAF 100/582 reads (17%) | catalogued as rs761906166; called by muse, mutect2, varscan2
- FICD | c.643C>T p.L215= | Silent (SNP) | VAF 16/478 reads (3%) | called by muse, mutect2
- FLG2 | c.6609A>G p.Q2203= | Silent (SNP) | VAF 148/403 reads (37%) | catalogued as rs766057290; called by muse, mutect2, varscan2
- GABRG2 | c.180A>G p.K60= | Silent (SNP) | VAF 53/330 reads (16%) | catalogued as COSV62715881; called by muse, mutect2, varscan2
- IFI30 | c.752G>A p.*251= | Silent (SNP) | VAF 36/186 reads (19%) | called by muse, mutect2, varscan2
- IL13RA2 | c.1020T>G p.T340= | Silent (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- INTS1 | c.1188C>T p.N396= | Silent (SNP) | VAF 61/430 reads (14%) | catalogued as rs1468728535; called by muse, mutect2, varscan2
- KNDC1 | c.4995G>A p.G1665= | Silent (SNP) | VAF 15/384 reads (4%) | called by muse, mutect2
- MAP1B | c.1884C>A p.V628= | Silent (SNP) | VAF 22/368 reads (6%) | called by muse, mutect2
- MAP3K9 | c.2305T>C p.L769= (on ENST00000554752 / NM_001284230.1; = p.L783= on NM_033141.4) | Silent (SNP) | VAF 79/519 reads (15%) | called by muse, mutect2, varscan2
- MARK4 | c.1881C>T p.V627= (on ENST00000262891 / NM_001199867.2; = p.S654L on NM_031417.4) | Silent (SNP) | VAF 133/433 reads (31%) | called by muse, mutect2, varscan2
- MFAP3 | c.225C>T p.L75= | Silent (SNP) | VAF 75/300 reads (25%) | catalogued as rs756056668; called by muse, mutect2, varscan2
- MGST3 | c.81C>T p.I27= | Silent (SNP) | VAF 14/394 reads (4%) | called by muse, mutect2
- MKRN3 | c.1480T>C p.L494= | Silent (SNP) | VAF 58/339 reads (17%) | catalogued as COSV58811069; called by muse, mutect2, varscan2
- MTUS2 | c.45G>A p.L15= | Silent (SNP) | VAF 141/376 reads (38%) | called by muse, mutect2, varscan2
- MTUS2 | c.46C>A p.R16= | Silent (SNP) | VAF 142/374 reads (38%) | called by muse, mutect2, varscan2
- MUC12 | c.15993C>T p.C5331= (on ENST00000379442; = p.C5188= on NM_001164462.1) | Silent (SNP) | VAF 23/614 reads (4%) | catalogued as rs1462869926; called by muse, mutect2
- MYO3A | c.2709G>A p.L903= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99778475; called by muse, mutect2, varscan2
- NBEAL2 | c.177A>C p.P59= | Silent (SNP) | VAF 31/305 reads (10%) | called by muse, mutect2
- NLGN2 | c.2310C>T p.T770= | Silent (SNP) | VAF 18/626 reads (3%) | called by muse, mutect2
- OR10X1 | c.492T>G p.A164= | Silent (SNP) | VAF 41/351 reads (12%) | catalogued as COSV63767018, COSV63768118; called by muse, mutect2, varscan2
- OR2T6 | c.90C>T p.V30= | Silent (SNP) | VAF 44/652 reads (7%) | called by muse, mutect2
- OR4C16 | c.414C>T p.V138= | Silent (SNP) | VAF 39/400 reads (10%) | catalogued as COSV58941841; called by muse, mutect2, varscan2
- OR51I1 | c.441T>G p.G147= | Silent (SNP) | VAF 108/367 reads (29%) | catalogued as COSV100972084; called by muse, mutect2, varscan2
- OR5H14 | c.126T>C p.N42= | Silent (SNP) | VAF 23/443 reads (5%) | catalogued as COSV101454079; called by muse, mutect2
- OR9H1P | c.735A>G p.G245= | Silent (SNP) | VAF 78/268 reads (29%) | called by muse, varscan2
- PCLO | c.15379A>C p.R5127= | Silent (SNP) | VAF 89/433 reads (21%) | catalogued as rs377710753; called by muse, mutect2, varscan2
- PCLO | c.9318A>G p.Q3106= | Silent (SNP) | VAF 114/592 reads (19%) | called by muse, mutect2, varscan2
- PDZRN3 | c.1938C>T p.F646= | Silent (SNP) | VAF 24/423 reads (6%) | catalogued as rs377558165; called by muse, mutect2
- PLEC | c.9606G>T p.G3202= (on ENST00000322810 / NM_201380.4; = p.G3092= on NM_000445.5) | Silent (SNP) | VAF 33/787 reads (4%) | catalogued as rs781934037; called by muse, mutect2
- PLEKHG5 | c.2634T>A p.P878= (on ENST00000400915 / NM_001042663.3; = p.P841= on NM_020631.6) | Silent (SNP) | VAF 108/492 reads (22%) | called by muse, mutect2, varscan2
- PPFIA2 | c.2610T>A p.T870= | Silent (SNP) | VAF 78/255 reads (31%) | called by muse, mutect2, varscan2
- PPP1R3A | c.2172A>G p.K724= | Silent (SNP) | VAF 106/559 reads (19%) | catalogued as rs1036837030, COSV99492793; called by muse, mutect2, varscan2
- PSG7 | c.360C>T p.Y120= | Silent (SNP) | VAF 59/348 reads (17%) | called by muse, mutect2, varscan2
- RHAG | c.609C>T p.S203= | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as rs773998727; called by muse, mutect2
- RNF183 | c.531C>T p.L177= | Silent (SNP) | VAF 30/367 reads (8%) | catalogued as rs1366763390; called by muse, mutect2
- SCRT2 | c.831C>T p.F277= | Silent (SNP) | VAF 39/822 reads (5%) | catalogued as rs1221558957; called by muse, mutect2
- SEMA5A | c.2742A>G p.Q914= | Silent (SNP) | VAF 62/354 reads (18%) | called by muse, mutect2, varscan2
- SIGLEC14 | c.1044G>A p.E348= | Silent (SNP) | VAF 21/517 reads (4%) | called by muse, mutect2
- SLC25A27 | c.642G>A p.V214= | Silent (SNP) | VAF 60/248 reads (24%) | catalogued as rs757183089; called by muse, mutect2, varscan2
- SLCO5A1 | c.639C>A p.A213= | Silent (SNP) | VAF 140/603 reads (23%) | called by muse, mutect2, varscan2
- SYTL2 | c.705C>T p.P235= | Silent (SNP) | VAF 77/329 reads (23%) | called by muse, mutect2, varscan2
- TDRD15 | c.3433A>C p.R1145= | Silent (SNP) | VAF 83/200 reads (42%) | called by muse, mutect2, varscan2
- TENM2 | c.2538T>G p.T846= (on ENST00000518659 / NM_001122679.2; = p.T614= on NM_001080428.3) | Silent (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- THBS2 | c.321T>C p.G107= | Silent (SNP) | VAF 12/445 reads (3%) | called by muse, mutect2
- TMEM94 | c.1950G>A p.E650= | Silent (SNP) | VAF 66/382 reads (17%) | catalogued as rs1265118487; called by muse, mutect2, varscan2
- TRIOBP | c.2346T>G p.S782= | Silent (SNP) | VAF 91/466 reads (20%) | called by muse, mutect2, varscan2
- TRMT2B | c.948C>T p.I316= | Silent (SNP) | VAF 18/294 reads (6%) | called by muse, mutect2
- TRPC5 | c.2178T>A p.A726= | Silent (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- TRPM6 | c.906A>C p.S302= | Silent (SNP) | VAF 24/440 reads (5%) | called by muse, mutect2
- TYW1B | c.1725C>T p.P575= | Silent (SNP) | VAF 72/756 reads (10%) | catalogued as COSV100646639; called by muse, mutect2
- WDR83 | c.525G>A p.V175= | Silent (SNP) | VAF 20/368 reads (5%) | catalogued as COSV52952676, COSV99269680; called by muse, mutect2
- XPR1 | c.1215G>C p.V405= | Silent (SNP) | VAF 26/480 reads (5%) | catalogued as COSV62554774, COSV62555901; called by muse, mutect2
- ZNF236 | c.3753C>T p.F1251= | Silent (SNP) | VAF 12/335 reads (4%) | called by muse, mutect2
- ZNF474 | c.924T>C p.T308= | Silent (SNP) | VAF 87/369 reads (24%) | catalogued as COSV56947461; called by muse, mutect2, varscan2
- ZNF568 | c.309A>G p.E103= | Silent (SNP) | VAF 24/398 reads (6%) | called by muse, mutect2
- ZNF57 | c.870T>G p.T290= | Silent (SNP) | VAF 16/388 reads (4%) | called by muse, mutect2
- ZNF800 | c.1917T>C p.T639= | Silent (SNP) | VAF 71/225 reads (32%) | called by muse, mutect2, varscan2
- AL627230.3 | c.76-129G>A | Intron (SNP) | VAF 77/720 reads (11%) | catalogued as rs1485831365; called by muse, mutect2, varscan2
- DPF3 | c.871+3023C>T | Intron (SNP) | VAF 109/384 reads (28%) | catalogued as rs751189350, COSV63503241; called by muse, mutect2, varscan2
- PDPN | c.67+63T>G | Intron (SNP) | VAF 68/373 reads (18%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532485 T>G | 5'Flank (SNP) | VAF 36/291 reads (12%) | catalogued as rs563725594, COSV99041141; called by muse, mutect2, varscan2
- TTN | c.10360+5095T>G | Intron (SNP) | VAF 160/403 reads (40%) | catalogued as COSV60400229; called by muse, mutect2, varscan2
